Surgical pathology report (de-identified scan), TCGA case TCGA-O2-A52W, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - CALGB, specimen TCGA-O2-A52W-01A (Primary Tumor).

[page 1 of 4]
Patient

ICD-O-3

Surg Path

*Adenocarcinoma,
squamous cell NOS
8070/3
Site: R Lower & middle
lobes C84.2
7/2/22/13*

CLINICAL HISTORY:
Lung cancer.

GROSS EXAMINATION:

- A. "2R lymph node (AF1)", received fresh for frozen section is a 0.4 x 0.4 x 0.3 cm fragment of tan tissue previously frozen as AF1 and the frozen remnant is entirely submitted in block A1.
- B. "Level 3 lymph node (BF1)", received fresh for frozen section is a 0.5 x 0.4 x 0.2 cm fragment of tan-pink tissue previously frozen as BF1 and the frozen remnant is entirely submitted in block B1. Also received is a 0.2 x 0.1 x 0.1 cm fragment of tan-gray tissue that is submitted entirely in block B2.
- C. "4R lymph node (CF1)", received fresh for frozen section is a 0.9 x 0.4 x 0.4 cm aggregate of tan-gray and black tissue previously frozen as CF1 and the frozen remnant is submitted in block C1.
- D. "4L lymph node (DF1)", received fresh for frozen section is a 0.4 x 0.4 x 0.3 cm fragment of tan-pink tissue previously frozen as DF1 and the frozen remnant is entirely submitted in block D1.
- E. "Level 7 lymph node (EF1)", received fresh for frozen section is a 0.8 x 0.5 x 0.3 cm aggregate of black and red tissue previously frozen as EF1 and the frozen remnant is entirely submitted in block E1. Also received is a 0.4 x 0.3 x 0.2 cm aggregate of red and black tissue entirely submitted in block E2.

INTRA OPERATIVE CONSULTATION:

- A. "2R lymph node": AF1- negative for malignancy
B. "Level 3 lymph node": BF1- negative for malignancy
C. "4R lymph node": CF1- negative for malignancy
D. "4L lymph node": DF1- negative for malignancy
E. "Level 7 lymph node": EF1- negative for malignancy

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

DIAGNOSIS:

- A. "2R LYMPH NODE" (BIOPSY):

PROFILES OF LYMPH NODE, NO EVIDENCE OF MALIGNANCY.

- B. "LEVEL 3 LYMPH NODE" (BIOPSY):

PROFILES OF LYMPH NODE, NO EVIDENCE OF MALIGNANCY.

- C. "4R LYMPH NODE" (BIOPSY):

PROFILES OF LYMPH NODE, NO EVIDENCE OF MALIGNANCY.

- D. "4L LYMPH NODE" (BIOPSY):

FIBROVASCULAR AND ADIPOSE TISSUE, NO LYMPHOID TISSUE IDENTIFIED.

[page 2 of 4]
NO EVIDENCE OF MALIGNANCY.

E. "LEVEL 7" (BIOPSY):

PROFILES OF LYMPH NODE, NO EVIDENCE OF MALIGNANCY.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed.

Performed by:

Two horizontal black redaction bars, one above the other, obscuring text in the signature area.

[page 3 of 4]
Patient: |

Surg Path

CLINICAL HISTORY:

Lung nodule (history of right lower mass-per surgeon).

GROSS EXAMINATION:

A. "Level 11 (AF1)", received fresh for frozen section is a 0.5 x 0.4 x 0.3 cm aggregate of brown-tan tissue which has been entirely frozen as AF1, the frozen section remnant of which is submitted in block A1.

B. "Right, lower lobe lung and middle (BF1)", received fresh for frozen section is a 480 gram, 20 x 17 x 8.2 cm lobectomy specimen. The pleura demonstrates a 4.5 x 4 cm area of puckering and white discoloration as well as focal areas of hemorrhagic focal adhesions. Serial sectioning demonstrates a 5 x 4.7 x 2.2 cm well-circumscribed central necrotic mass directly abutting the aforementioned area of pleural retraction and discoloration and 5.3 cm from the bronchial margin. The remainder of the parenchymal cut surface demonstrates a moderate amount of emphysematous change, but is otherwise crepitant and brown-tan. The bronchial mucosa is trabeculated white-tan with no abnormalities noted. A representative section of the bronchial margin has been previously frozen as BF1, the frozen section remnant of which is submitted in block B1. Additional representative sections are submitted as follows:

BLOCK SUMMARY:

- B2- vascular margins
- B3- lobar lymph node candidates
- B4-5 sections of mass with respect to pleura (A VVG stain is prospectively requested in B4)
- B6- mass with adjacent uninvolved
- B7- central section of mass
- B8-9 sections of uninvolved parenchyma

C. "Level 7", received in formalin is a 5 x 4 x 3 cm aggregate of brown-tan soft tissue which is sectioned and submitted entirely in blocks C1-2.

D. "4R lymph node", received in formalin is a 6 x 5 x 4 cm aggregate of yellow-tan soft tissue which is serially sectioned and entirely submitted in blocks D1-2.

E. "Level 8", received in formalin is a 0.5 x 0.4 x 0.2 cm aggregate of brown-tan soft tissue which is submitted entirely in block E1.

INTRA OPERATIVE CONSULTATION:

A. "Level 11":AF1-no tumor is seen

B. "Right, lower and middle lobe lung":BF1-bronchial margin is negative for tumor

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: BILOBECTOMY; MEDIASTINAL LYMPH NODE BIOPSIES

PATHOLOGIC STAGE (AJCC 6th Edition): pT2 pN0 pMx

[page 4 of 4]
NOTE: Information on pathology stage and the operative procedure is transmitted to this Institution's Cancer Registry as required for accreditation by the Commission on Cancer. Pathology stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A. "LEVEL 11" (BIOPSY):

PROFILES OF LYMPH NODE, NO EVIDENCE OF MALIGNANCY.
A SILICOTIC NODULE IS PRESENT.

B. "RIGHT LOWER LOBE LUNG AND MIDDLE" (BILOBECTOMY):

CARCINOMA OF LUNG:

Histologic type: SQUAMOUS CELL
Histologic grade: MODERATELY DIFFERENTIATED (G2)

Extent of invasion

- Max. tumor diameter: 5 CM
- Mainstem bronchus: NEGATIVE
- Visceral pleura: NEGATIVE, CONFIRMED ON ELASTIN VVG STAIN
- Chest wall: NEGATIVE
- Mediastinum: NEGATIVE
- >1 tumor nodules? NEGATIVE
- Panlobar atelectasis? NEGATIVE

Margins

- Bronchial: NEGATIVE
- Vascular: NEGATIVE
- Parenchymal: NEGATIVE
- Pleural: NEGATIVE

Other prognostic features

- Vascular invasion: PRESENT

Regional lymph nodes: SIX PERIBRONCHIAL LYMPH NDOES, NO EVIDENCE OF MALIGNANCY.

Additional findings: CNETRILOBULAR EMPHYSEMA

C. "LEVEL 7" (BIOPSY):

PROFILES OF LYMPH NODE, NO EVIDENCE OF MALIGNANCY.

D. "4R LYMPH NODE" (BIOPSY):

PROFILES OF LYMPH NODE, NO EVIDENCE OF MALIGNANCY.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Performed by:

Electronically signed:

Patient: [REDACTED]

Source: NCI Genomic Data Commons file 670dc9e4-6292-44f7-bcce-d7d17c85e685 (TCGA-O2-A52W.40AC1B86-4305-482C-A6DE-45E1320676C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).